Somatic mutation profile of tumor specimen C3N-01078-02 (aliquot CPT0210950006) from CPTAC case C3N-01078, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Tumor grade: G2.
Specimen C3N-01078-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56941a85-c4b6-46dc-8e69-0a48a00c60d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01078-71 (Blood Derived Normal), aliquot CPT0211060002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32e4e189-7303-4e37-be7b-3dfef1f97698

The open-access MAF lists 76 somatic variants for this specimen: 56 protein-altering or splice-affecting, 15 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 15, Frame Shift Del 5, Nonsense Mutation 3, 5'UTR 2, Frame Shift Ins 2, In Frame Del 1, Splice Site 1, Intron 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.233A>G p.N78S | Missense Mutation (SNP) | VAF 163/528 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as rs5030804, CM951271, CM951272, HM971371, COSV56543460, COSV56543998, COSV56546634, COSV56559393; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CD46 | c.92_94del p.F31del | In Frame Del (DEL) | VAF 108/531 reads (20%) | catalogued as rs777485215; called by mutect2, pindel, varscan2
- FAM189B | c.1867G>C p.E623Q | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as COSV100516463; called by muse, mutect2, varscan2
- FLG2 | c.4180C>A p.Q1394K | Missense Mutation (SNP) | VAF 68/330 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.587); catalogued as COSV101166289; called by muse, mutect2, varscan2
- GASK1B | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 57/236 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV56711972; called by muse, mutect2, varscan2
- GZF1 | c.2107C>A p.Q703K | Missense Mutation (SNP) | VAF 53/303 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.027); catalogued as rs573434420; called by muse, mutect2, varscan2
- HAND2 | c.281G>T p.G94V | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.101); catalogued as rs140589459; called by muse, mutect2, varscan2
- SALL3 | c.3439G>A p.G1147S | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1455914542; called by mutect2, varscan2
- SLC24A1 | c.3176T>C p.I1059T | Missense Mutation (SNP) | VAF 76/356 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs775295158; called by muse, mutect2, varscan2
- SMC1A | c.2078G>A p.R693Q | Missense Mutation (SNP) | VAF 270/846 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587784408, CM1310840, COSV100447775; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- STXBP5 | c.631C>G p.L211V | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs765084169; called by muse, mutect2
- TEX33 | c.593A>T p.Y198F (on ENST00000381821 / NM_001163857.2; = p.Y113F on NM_178552.4) | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.204); catalogued as rs1373462312, COSV67822686; called by muse, mutect2, varscan2
- ZNF326 | c.31G>T p.A11S | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.045); catalogued as COSV61036825; called by muse, mutect2, varscan2
- ZNF469 | c.1181C>T p.T394M | Missense Mutation (SNP) | VAF 24/596 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs1031189046; called by muse, mutect2
- AKAP17A | c.323A>G p.D108G | Missense Mutation (SNP) | VAF 51/236 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- AKAP3 | c.2236G>T p.G746* | Nonsense Mutation (SNP) | VAF 65/257 reads (25%) | called by muse, mutect2, varscan2
- ASMT | c.229A>G p.T77A | Missense Mutation (SNP) | VAF 284/697 reads (41%) | SIFT tolerated (0.65); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- ATP6V0A2 | c.2249C>T p.T750I | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CASS4 | c.2162G>A p.C721Y | Missense Mutation (SNP) | VAF 64/248 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- CENPT | c.589C>A p.L197I | Missense Mutation (SNP) | VAF 50/193 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- CMYA5 | c.172G>T p.G58* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | called by mutect2, varscan2
- COL6A5 | c.4566C>A p.N1522K | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- CRY1 | c.622del p.A208Qfs*32 | Frame Shift Del (DEL) | VAF 47/253 reads (19%) | called by mutect2, pindel, varscan2
- DAB2IP | c.2137G>A p.V713I (on ENST00000408936; = p.V685I on NM_032552.3) | Missense Mutation (SNP) | VAF 39/234 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DIP2A | c.2743_2744del p.Q915Afs*11 | Frame Shift Del (DEL) | VAF 83/491 reads (17%) | called by mutect2, pindel, varscan2
- DNAH5 | c.8048del p.N2683Mfs*6 | Frame Shift Del (DEL) | VAF 63/262 reads (24%) | called by mutect2, pindel, varscan2
- DUS1L | c.364C>A p.L122M | Missense Mutation (SNP) | VAF 61/316 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ECE2 | c.110C>A p.S37Y | Missense Mutation (SNP) | VAF 76/282 reads (27%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EED | c.1238T>C p.I413T | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- EIF1 | c.76G>T p.G26C | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- FAH | c.877T>C p.Y293H | Missense Mutation (SNP) | VAF 81/421 reads (19%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- FUT6 | c.45_46dup p.C16Sfs*3 | Frame Shift Ins (INS) | VAF 41/185 reads (22%) | called by mutect2, pindel, varscan2
- GAS6 | c.1582C>G p.P528A | Missense Mutation (SNP) | VAF 58/252 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- GINS1 | c.199_209del p.C67Kfs*12 | Frame Shift Del (DEL) | VAF 34/242 reads (14%) | called by mutect2, pindel, varscan2
- GPR21 | c.71C>A p.T24N | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- GTF3C2 | c.1443G>C p.W481C | Missense Mutation (SNP) | VAF 65/238 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- IL5RA | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 6/151 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- LEO1 | c.1640T>C p.I547T | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MKI67 | c.8048C>T p.T2683I | Missense Mutation (SNP) | VAF 16/349 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2
- NBPF26 | c.2341G>T p.E781* (on ENST00000620612; = p.E519* on NM_001351372.1) | Nonsense Mutation (SNP) | VAF 17/500 reads (3%) | called by muse, mutect2
- NEXMIF | c.1027A>G p.T343A | Missense Mutation (SNP) | VAF 41/290 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NWD2 | c.671_672insTT p.M224Ifs*2 | Frame Shift Ins (INS) | VAF 30/110 reads (27%) | called by mutect2, pindel, varscan2
- PAPOLG | c.1678_1679+4del p.X560_splice | Splice Site (DEL) | VAF 25/213 reads (12%) | called by mutect2, pindel, varscan2
- PLAA | c.2195T>C p.I732T | Missense Mutation (SNP) | VAF 68/242 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PRUNE2 | c.6325C>A p.H2109N | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- RYR1 | c.7990T>G p.F2664V | Missense Mutation (SNP) | VAF 62/342 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SAXO1 | c.590G>A p.C197Y | Missense Mutation (SNP) | VAF 76/363 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SCG3 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- SLC26A6 | c.845T>A p.L282Q | Missense Mutation (SNP) | VAF 70/246 reads (28%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- SMTNL2 | c.29C>A p.A10E | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TIPARP | c.1483A>G p.I495V | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.383); called by muse, mutect2
- TUT4 | c.3798T>G p.F1266L | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- USP2 | c.741del p.S248Afs*11 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | called by mutect2, varscan2
- ZFP64 | c.2036T>G p.I679S | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- ZNF292 | c.1447G>T p.V483L | Missense Mutation (SNP) | VAF 63/249 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNFX1 | c.804G>A p.M268I | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ADGRB1 | c.1665G>A p.G555= | Silent (SNP) | VAF 20/105 reads (19%) | called by muse, mutect2, varscan2
- CWF19L2 | c.1224C>A p.P408= | Silent (SNP) | VAF 33/158 reads (21%) | called by muse, mutect2, varscan2
- GABPB2 | c.519T>C p.P173= | Silent (SNP) | VAF 76/300 reads (25%) | catalogued as rs779602717; called by muse, mutect2, varscan2
- GFOD2 | c.1044G>T p.V348= | Silent (SNP) | VAF 57/330 reads (17%) | called by muse, mutect2, varscan2
- HSPG2 | c.9630G>T p.G3210= | Silent (SNP) | VAF 81/382 reads (21%) | called by muse, mutect2, varscan2
- IQCD | c.1326G>A p.K442= (on ENST00000416617 / NM_001330452.2; = p.K340= on NM_138451.3) | Silent (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2, varscan2
- MAGEB2 | c.756G>C p.L252= | Silent (SNP) | VAF 117/272 reads (43%) | catalogued as COSV100975570; called by muse, mutect2, varscan2
- MIER2 | c.324G>A p.E108= | Silent (SNP) | VAF 12/181 reads (7%) | catalogued as COSV99315835; called by muse, mutect2
- MUC12 | c.3261C>T p.S1087= (on ENST00000379442; = p.S944= on NM_001164462.1) | Silent (SNP) | VAF 38/868 reads (4%) | called by muse, mutect2
- OR4C5 | c.888C>T p.N296= | Silent (SNP) | VAF 42/301 reads (14%) | called by muse, mutect2, varscan2
- OR8A1 | c.735A>G p.A245= | Silent (SNP) | VAF 9/183 reads (5%) | called by muse, mutect2
- PAGE2B | c.60T>C p.S20= | Silent (SNP) | VAF 19/234 reads (8%) | called by muse, mutect2
- SAFB2 | c.2493G>A p.L831= | Silent (SNP) | VAF 41/177 reads (23%) | called by muse, mutect2, varscan2
- VPS13C | c.6567A>T p.G2189= (on ENST00000644861 / NM_020821.3; = p.G2146= on NM_017684.5) | Silent (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- ZNFX1 | c.805C>T p.L269= | Silent (SNP) | VAF 21/102 reads (21%) | called by muse, mutect2, varscan2
- AATF | c.*4C>T | 3'UTR (SNP) | VAF 50/238 reads (21%) | catalogued as rs999448953; called by muse, mutect2, varscan2
- GPR35 | c.-50G>T | 5'UTR (SNP) | VAF 63/269 reads (23%) | called by muse, mutect2, varscan2
- MRGPRG | chr11:3222055 C>A | 5'Flank (SNP) | VAF 10/304 reads (3%) | called by muse, mutect2
- PARVG | c.-284G>A | 5'UTR (SNP) | VAF 28/245 reads (11%) | catalogued as rs772085472; called by muse, mutect2, varscan2
- ZEB1 | c.58+43584T>G | Intron (SNP) | VAF 52/204 reads (25%) | called by muse, mutect2, varscan2
